Somatic mutation profile of tumor specimen 0DJ6KQ from CCDI case PBBWSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.7 years (638 days).
Specimen 0DJ6KQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be536262-3033-4ab9-852a-1a8a0ffe9a3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ6K6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22ba2fb2-4b5c-4728-9636-7b0d5fde5bac

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 238/520 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DNMT1 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 25/756 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61583569; called by muse, mutect2
- KMT2D | c.4435C>T p.Q1479* | Nonsense Mutation (SNP) | VAF 295/684 reads (43%) | catalogued as COSV56434785; called by muse, mutect2, varscan2
- PTCH1 | c.1308_1309insA p.V437Sfs*60 | Frame Shift Ins (INS) | VAF 386/853 reads (45%) | catalogued as COSV59498182; called by pindel, varscan2
- UTY | c.2906G>A p.R969H | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs547367934; called by muse, mutect2
- CDH23 | c.183C>A p.D61E | Missense Mutation (SNP) | VAF 80/878 reads (9%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXW7 | c.1621A>G p.T541A (on ENST00000281708 / NM_001349798.2; = p.T461A on NM_018315.5) | Missense Mutation (SNP) | VAF 24/469 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.343); called by muse, mutect2
- POLR2K | c.131T>A p.M44K | Missense Mutation (SNP) | VAF 111/452 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PTCH1 | c.1274_1280del p.T425Rfs*5 | Frame Shift Del (DEL) | VAF 248/727 reads (34%) | called by pindel, varscan2
- PCDHA2 | c.1353C>T p.N451= | Silent (SNP) | VAF 70/881 reads (8%) | catalogued as rs376199248; called by muse, mutect2
